Somatic mutation profile of tumor specimen 07c4bb93-a373-4748-a2c7-5806cb (aliquot 07c4bb93-a373-4748-a2c7-5806cb_D6_1) from CPTAC case 11BR069, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.0 years (23,755 days).
Specimen 07c4bb93-a373-4748-a2c7-5806cb: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7f3982b-224a-44bd-acef-2d6e6f70c9d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ea97a4cf-4acb-47f5-b19f-1e8d4a (Blood Derived Normal), aliquot ea97a4cf-4acb-47f5-b19f-1e8d4a_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2949cee7-39eb-40eb-a60d-ba9439fa222e

The open-access MAF lists 48 somatic variants for this specimen: 29 protein-altering or splice-affecting, 12 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 12, Intron 4, Splice Region 3, Frame Shift Del 2, RNA 2, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS16 | c.1856C>A p.S619* | Nonsense Mutation (SNP) | VAF 12/77 reads (16%) | catalogued as COSV56976236; called by muse, mutect2, varscan2
- CHRD | c.2027C>T p.S676F | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV52608284, COSV99200258; called by muse, mutect2, varscan2
- HLCS | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 221/679 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs201215058, COSV60793799; called by muse, mutect2, varscan2
- KIRREL1 | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 28/353 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs752436479, COSV63284959, COSV63290141; called by muse, mutect2
- MATR3 | c.883A>G p.I295V | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as rs1295380909; called by muse, mutect2, varscan2
- METTL23 | c.407+4A>C | Splice Region (SNP) | VAF 19/102 reads (19%) | catalogued as rs762132582; called by muse, mutect2, varscan2
- MTMR1 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV64892421; called by muse, mutect2, varscan2
- OR5D14 | c.508T>C p.F170L | Missense Mutation (SNP) | VAF 60/358 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV59456459; called by muse, mutect2, varscan2
- STRC | c.4247G>A p.R1416Q | Missense Mutation (SNP) | VAF 70/344 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0.107); catalogued as rs751324121; called by muse, mutect2, varscan2
- TRIO | c.9113G>A p.R3038H | Missense Mutation (SNP) | VAF 58/405 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773355648, COSV59992700; called by muse, mutect2, varscan2
- ZNF714 | c.1583T>A p.V528D | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.972); catalogued as rs1426276770; called by muse, varscan2
- AC023469.1 | n.217G>T | Splice Region (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- ARFRP1 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT tolerated (0.94); PolyPhen benign (0.001); called by muse, mutect2
- ATG13 | c.1436T>C p.L479P (on ENST00000359513 / NM_001346321.1; = p.L442P on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- BRINP1 | c.1900G>T p.G634C | Missense Mutation (SNP) | VAF 38/276 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- BTBD3 | c.215C>G p.P72R | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CAPN10 | c.1304_1305del p.P435Qfs*25 | Frame Shift Del (DEL) | VAF 24/191 reads (13%) | called by mutect2, pindel, varscan2
- FOXF1 | c.1090T>C p.Y364H | Missense Mutation (SNP) | VAF 68/494 reads (14%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- GATA3 | c.1219_1220del p.S407Afs*99 | Frame Shift Del (DEL) | VAF 42/182 reads (23%) | called by pindel, varscan2
- GNB1L | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 76/440 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- GPS2 | c.397+2dup | Splice Region (INS) | VAF 71/170 reads (42%) | called by mutect2, pindel, varscan2
- HSPD1 | c.945T>G p.D315E | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- INSRR | c.1532C>A p.A511D | Missense Mutation (SNP) | VAF 40/353 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.374); called by muse, mutect2
- ITM2C | c.76C>G p.P26A | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOC3L | c.83T>C p.L28P | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLAUR | c.446C>A p.T149N | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- PPP1R13L | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- SHTN1 | c.349A>G p.I117V | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.106); called by muse, mutect2
- SLC25A14 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ABCB6 | c.2049T>C p.N683= | Silent (SNP) | VAF 37/338 reads (11%) | called by muse, mutect2, varscan2
- ADAMTS9 | c.1722T>C p.Y574= | Silent (SNP) | VAF 21/102 reads (21%) | called by muse, mutect2, varscan2
- CYP51A1 | c.222T>A p.I74= | Silent (SNP) | VAF 5/32 reads (16%) | called by mutect2, varscan2
- CYP8B1 | c.21G>T p.V7= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- HIVEP2 | c.5205C>G p.S1735= | Silent (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- INCENP | c.399G>A p.A133= | Silent (SNP) | VAF 107/484 reads (22%) | catalogued as rs758789600, COSV53915542; called by muse, mutect2, varscan2
- OR5B21 | c.651C>T p.F217= | Silent (SNP) | VAF 46/206 reads (22%) | catalogued as rs267603028, COSV64482092; called by muse, mutect2, varscan2
- P3H1 | c.2154C>T p.P718= | Silent (SNP) | VAF 54/331 reads (16%) | catalogued as rs775626323, COSV52532098; called by muse, mutect2, varscan2
- PLXNA1 | c.3330C>T p.A1110= | Silent (SNP) | VAF 293/722 reads (41%) | called by muse, mutect2, varscan2
- PRR35 | c.1461C>T p.P487= | Silent (SNP) | VAF 31/290 reads (11%) | catalogued as rs756560859; called by muse, mutect2, varscan2
- SPG11 | c.3888T>A p.S1296= | Silent (SNP) | VAF 38/208 reads (18%) | called by muse, mutect2, varscan2
- UBR4 | c.14664C>T p.Y4888= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as rs774084223, COSV64392967; called by mutect2, varscan2
- CELF2 | c.1076-2067C>T | Intron (SNP) | VAF 52/256 reads (20%) | catalogued as rs1476659755; called by muse, mutect2, varscan2
- FOXRED1 | c.306+44A>T | Intron (SNP) | VAF 24/104 reads (23%) | called by muse, mutect2, varscan2
- KBTBD4 | c.-30+252G>A | Intron (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- OFCC1 | n.220_221del | RNA (DEL) | VAF 12/106 reads (11%) | called by mutect2, pindel, varscan2
- TBC1D21 | c.-18C>T | 5'UTR (SNP) | VAF 31/169 reads (18%) | catalogued as rs375143943; called by muse, mutect2, varscan2
- ZNF295-AS1 | n.195C>T | RNA (SNP) | VAF 64/609 reads (11%) | catalogued as rs544884080; called by muse, mutect2, varscan2
- ZSCAN9 | c.568+111G>T | Intron (SNP) | VAF 21/105 reads (20%) | called by muse, mutect2, varscan2
